Somatic mutation profile of tumor specimen 0DBU0X from CCDI case PBBLIX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pinealoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,653 days).
Specimen 0DBU0X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 294ebfc5-406b-4421-b3d1-e213705cbc96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBU0V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7e971d0-279b-48cc-b8d8-eff32443424f

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF207 | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 52/788 reads (7%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs756703950; called by muse, mutect2
- KBTBD4 | c.884_889dup p.P295_R296dup | In Frame Ins (INS) | VAF 100/252 reads (40%) | called by mutect2, varscan2
- KMT2C | c.1354A>T p.N452Y | Missense Mutation (SNP) | VAF 26/827 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ORMDL1 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 50/1254 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2
- C10orf71 | c.2040A>G p.T680= | Silent (SNP) | VAF 24/408 reads (6%) | called by muse, mutect2
- PXDNL | c.3174A>T p.T1058= | Silent (SNP) | VAF 194/486 reads (40%) | called by mutect2, varscan2
- IFI6 | c.*59G>A | 3'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2
